Somatic mutation profile of tumor specimen MP2PRT-PANWDL-TMP1-A (aliquot MP2PRT-PANWDL-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANWDL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Blastic plasmacytoid dendritic cell neoplasm; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,414 days).
Specimen MP2PRT-PANWDL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04dddd09-6011-49dd-b42b-99ba3d90d8f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANWDL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANWDL-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/936eefbc-281b-4b59-bed5-fd6c39461b36

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Frame Shift Ins 3, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR2 | c.13666G>A p.A4556T | Missense Mutation (SNP) | VAF 101/517 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs189345192, CM056385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLITRK3 | c.2039G>A p.R680Q | Missense Mutation (SNP) | VAF 26/544 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1383137176, COSV53854217, COSV99579168; called by muse, mutect2
- NPAT | c.1681_1682insGG p.K561Rfs*21 | Frame Shift Ins (INS) | VAF 28/145 reads (19%) | called by mutect2, pindel, varscan2
- SLC4A3 | c.2224G>T p.E742* | Nonsense Mutation (SNP) | VAF 149/503 reads (30%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.260_261insTT p.M88* | Frame Shift Ins (INS) | VAF 92/260 reads (35%) | called by mutect2, varscan2
- TBL1XR1 | c.259delinsCTT p.V87Lfs*2 | Frame Shift Ins (INS) | VAF 106/297 reads (36%) | called by mutect2*, pindel, varscan2*
- TSPAN31 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CYP11B1 | c.288C>T p.D96= | Silent (SNP) | VAF 38/614 reads (6%) | catalogued as rs5284; ClinVar: likely benign; called by muse, mutect2
- KCNB2 | c.1425C>T p.S475= | Silent (SNP) | VAF 160/399 reads (40%) | catalogued as COSV73049433; called by muse, mutect2, varscan2
- NOTUM | c.1482C>T p.N494= | Silent (SNP) | VAF 69/279 reads (25%) | catalogued as rs777868773, COSV104433690; called by muse, mutect2, varscan2
